Somatic mutation profile of tumor specimen TCGA-B5-A121-01A (aliquot TCGA-B5-A121-01A-31D-A122-09) from TCGA case TCGA-B5-A121, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 57.5 years (21,018 days).
Specimen TCGA-B5-A121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 488c55c1-57b2-46be-bc59-969d69796a92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A121-10A (Blood Derived Normal), aliquot TCGA-B5-A121-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/713b8c2c-67d8-41cb-87d8-0df476d574cf

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 55/120 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 66/116 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NAA15 | c.228_232del p.D76Efs*20 | Frame Shift Del (DEL) | VAF 113/331 reads (34%) | catalogued as rs1380822792; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AMY1A | c.1092A>T p.E364D | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100915809; called by mutect2, varscan2
- ARID1A | c.3562C>T p.Q1188* | Nonsense Mutation (SNP) | VAF 75/267 reads (28%) | catalogued as COSV61373578; called by muse, mutect2, varscan2
- CDK14 | c.1295-2A>G p.X432_splice (on ENST00000380050 / NM_001287135.2; = p.X414_splice on NM_012395.3) | Splice Site (SNP) | VAF 75/213 reads (35%) | catalogued as COSV56027103; called by muse, mutect2, varscan2
- CNPY4 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as rs757977425, COSV53541999; called by muse, mutect2, varscan2
- CSMD3 | c.5982C>A p.D1994E (on ENST00000297405 / NM_001363185.1; = p.D1890E on NM_052900.3) | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.358); catalogued as COSV52126545; called by muse, mutect2, varscan2
- DCAF15 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54335374; called by muse, mutect2, varscan2
- DRG1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 165/444 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58918184; called by muse, mutect2, varscan2
- DRP2 | c.2477C>A p.A826E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV67870752; called by muse, mutect2, varscan2
- EDN1 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65080522; called by muse, mutect2, varscan2
- ENO1 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.55); catalogued as rs962155672, COSV52303031; called by muse, mutect2, varscan2
- F2 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs766630805, COSV61315084; called by muse, mutect2, varscan2
- GAA | c.944G>C p.S315T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV56407428; called by muse, mutect2, varscan2
- H3-3B | c.128+1G>T p.X43_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV54665696; called by muse, mutect2, varscan2
- MTA1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100495449; called by muse, mutect2
- MTA3 | c.1457C>G p.T486S | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV63196861; called by muse, mutect2, varscan2
- MYO9B | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575312769, COSV68277709; called by muse, mutect2, varscan2
- NIPBL | c.6440T>A p.V2147D | Missense Mutation (SNP) | VAF 20/619 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99243232; called by muse, mutect2
- PLA2G2E | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV64290340; called by muse, mutect2, varscan2
- RAG2 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV57556809; called by muse, mutect2, varscan2
- RAPGEF4 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51381089, COSV99911371; called by muse, mutect2, varscan2
- ROBO1 | c.2429T>G p.V810G | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV71392526; called by muse, mutect2, varscan2
- XPO1 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV68945027; called by muse, mutect2, varscan2
- ACTL10 | c.663dup p.F222Lfs*? | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- IFNA17 | c.456_457del p.Y153Sfs*45 | Frame Shift Del (DEL) | VAF 95/480 reads (20%) | called by mutect2, pindel, varscan2
- LRIG3 | c.1439del p.G480Efs*32 | Frame Shift Del (DEL) | VAF 46/149 reads (31%) | called by mutect2, pindel, varscan2
- ADAM21 | c.2055G>A p.P685= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as rs137950449, COSV50789518; called by muse, mutect2, varscan2
- F7 | c.996G>A p.T332= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs202240468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM3 | c.861C>T p.A287= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV64468647; called by muse, mutect2
- ITK | c.1371G>A p.E457= | Silent (SNP) | VAF 64/179 reads (36%) | catalogued as rs746321007, COSV70060813; called by muse, mutect2, varscan2
- MAML3 | c.528G>A p.Q176= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as COSV59072111; called by muse, mutect2, varscan2
- NUTM1 | c.477G>A p.P159= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs768665655, COSV61546295; called by muse, mutect2, varscan2
- RNF19B | c.672G>A p.P224= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs768161540, COSV52387003; called by muse, mutect2, varscan2
- ZBTB34 | c.1053G>A p.G351= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100044062; called by muse, mutect2
- MCF2 | chrX:139645568 C>T | 5'Flank (SNP) | VAF 67/213 reads (31%) | catalogued as COSV58480088; called by muse, mutect2, varscan2
